Gene-level copy-number profile of tumor specimen TCGA-L5-A4OS-01A from TCGA case TCGA-L5-A4OS, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-L5-A4OS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.2f13af87-2043-4143-b040-2da48b167da2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OS-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e6b21b4-096f-4ca7-8cc9-e4ad40455cbf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 10,730; copy number 2: 38,904; copy number 3: 7,535; copy number 4: 1,551; copy number 5: 909; copy number 6: 57; copy number 7: 10; copy number 8: 82; copy number 16: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OS-01A-11D-A28A-01): tumor purity 0.37, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,994,618–88,606,976, 6 genes (within-gene range 0–1): AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,091 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,681,156–53,813,733, 38 genes, copy number 6 (within-gene range 2–6): GNL3, AC104446.3, AC104446.1, SNORD19, SNORD19B, SNORD19C, SNORD69, GLT8D1, SPCS1, NEK4, AC104446.2, AC006254.2, AC006254.3, ITIH1, ITIH3, ITIH4, AC006254.1, ITIH4-AS1, MUSTN1, STIMATE-MUSTN1, STIMATE, MIR8064, AC099667.1, SFMBT1, AC096887.1, AC096887.2, SERBP1P3, RFT1, PRKCD, AC097015.1, TKT, DCP1A, Y_RNA, CACNA1D, SNORD38C, AC112218.1, AC092035.1, SNORD63.
- chr3:57,941,818–58,433,857, 14 genes, copy number 5: PPIAP16, FLNB, FLNB-AS1, AC137936.1, AC137936.2, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1.
- chr3:184,505,113–185,052,614, 10 genes, copy number 7 (within-gene range 3–7): LINC01839, LINC01840, EPHB3, MAGEF1, AC107294.2, LINC02069, AC107294.3, AC107294.1, AC107294.4, VPS8.
- chr6:31,053,450–31,463,705, 37 genes, copy number 5: HCG22, RNU6-1133P, C6orf15, PSORS1C1, CDSN, PSORS1C2, POLR2LP1, CCHCR1, TCF19, POU5F1, PSORS1C3, AL662844.4, HCG27, AL662844.3, AL662844.1, AL662844.2, HLA-C, USP8P1, RPL3P2, WASF5P, LINC02571, AL671883.1, HLA-B, MIR6891, AL671883.2, DHFRP2, AL671883.3, RNU6-283P, FGFR3P1, ZDHHC20P2, HLA-S, AL645933.2, MICA, AL645933.3, Y_RNA, LINC01149, AL645933.1.
- chr6:47,231,532–47,369,230, 2 genes, copy number 6: TNFRSF21, B3GNTL1P2.
- chr7:16,087,525–17,346,152, 22 genes, copy number 5 (within-gene range 3–5): CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3.
- chr9:104,927,553–105,239,221, 4 genes, copy number 6 (within-gene range 2–6): AL359182.1, CT70, AL591506.1, RN7SKP191.
- chr9:114,060,127–114,099,291, 2 genes, copy number 6: AMBP, KIF12.
- chr11:75,335,092–76,144,232, 28 genes, copy number 5: MIR326, RPS3, SNORD15A, SNORD15B, KLHL35, GDPD5, AP002815.1, SERPINH1, AP001922.5, MAP6, AP001922.6, AP001922.2, AP001922.4, MOGAT2, RN7SL786P, AP001922.1, DGAT2, AP001922.3, AP003031.1, UVRAG-DT, UVRAG, Y_RNA, Y_RNA, PPP1R1AP1, AP003168.2, RNA5SP344, AP003168.1, AP002340.1.
- chr11:93,535,468–94,114,208, 30 genes, copy number 5–8: SRP14P2, RN7SL223P, AP003499.5, AP003499.4, AP003499.1, CEP295, Y_RNA, SCARNA9, AP003499.3, AP003499.2, AP001273.1, TAF1D, SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40, C11orf54, AP001273.2, MED17, VSTM5, Y_RNA, AP002795.1, HPRT1P3, HEPHL1, PHBP16.
- chr11:111,040,098–111,561,745, 22 genes, copy number 5: RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2, AP002448.1, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4, AP002008.4, MIR34B, MIR34C, AP002008.1, HOATZ, LAYN.
- chr11:129,375,848–129,538,114, 2 genes, copy number 5: BARX2, RPS27P20.
- chr13:73,100,575–73,661,891, 8 genes, copy number 5: FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr14:90,847,861–91,225,632, 4 genes, copy number 5 (within-gene range 2–5): RPS6KA5, DGLUCY, RNU7-30P, SNORA11B.
- chr15:84,631,451–84,873,479, 11 genes, copy number 6 (within-gene range 3–6): SCAND2P, WDR73, Metazoa_SRP, NMB, SEC11A, AC115102.1, AC012291.3, ZNF592, AC012291.2, ALPK3, AC012291.1.
- chr17:41,459,513–42,021,376, 33 genes, copy number 16 (within-gene range 3–16): KRT32, RNU2-32P, KRT35, KRT36, KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2, TTC25, CNP, DNAJC7.
- chr17:74,256,896–75,626,849, 71 genes, copy number 5 (broad region; genes not listed).
- chr17:75,633,434–75,641,404, 1 gene, copy number 5: SMIM5.
- chr19:28,869,507–30,872,507, 40 genes, copy number 8: AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1.
- chr19:40,890,826–41,062,444, 7 genes, copy number 5: CYP2G1P, CYP2A7P2, CYP2B7P, AC092071.1, CYP2B6, CYP2A7P1, CYP2G2P.
- chr20:17,187,510–18,381,484, 37 genes, copy number 5: RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2, AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851.
- chr20:37,101,226–64,313,132, 668 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,662. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
